Gene-level copy-number profile of tumor specimen TCGA-VS-A9U7-01A from TCGA case TCGA-VS-A9U7, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 30.7 years (11,210 days).
Specimen TCGA-VS-A9U7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.6f8e775b-700b-4f49-87cf-67a827c1b2a1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A9U7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/db9a2afb-e451-40f3-8931-78f18492bffb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 7,153; copy number 2: 47,112; copy number 3: 5,179; copy number 4: 167; copy number 5: 192; copy number 11: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A9U7-01A-11D-A42N-01): tumor purity 0.82, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,636,604–10,796,650, 2 genes: CASZ1, AL139423.1.
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr2:204,545,475–205,620,162, 1 gene (within-gene range 0–1): PARD3B.
- chr2:205,253,304–205,253,503, 1 gene: AC008171.1.
- chr3:60,616,822–60,690,719, 3 genes: AC104164.2, MIR548BB, PPIAP70.
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 193 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:175,234,861–184,508,399, 187 genes, copy number 5 (broad region; genes not listed).
- chr9:5,450,503–5,470,566, 1 gene, copy number 11 (within-gene range 0–11): CD274.
- chr11:78,652,829–79,441,030, 1 gene, copy number 5 (within-gene range 4–5): TENM4.
- chr11:79,092,848–79,422,226, 4 genes, copy number 5: AP002957.1, AP001547.1, MIR708, MIR5579.

Autosomal genes at a single copy (total copy number 1): 7,153. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
